CPTAC case C3L-00674 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e1bd6dfa-0567-46e7-991c-63eefaf5bd7a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1971; Vital status: Dead; Days to death: 478 days (1.3 years); Year of death: 2018; Cause of death: Cancer Related.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Frontal lobe; Age at diagnosis: 45.6 years (16,667 days); Year of diagnosis: 2016; Days to last known disease status: 478 days (1.3 years); Progression or recurrence: yes; Days to recurrence: 245 days; Days to last follow up: 385 days (1.1 years).
   Pathology details: Greatest tumor dimension: 2.5 cm (a second GDC size field records 4.9 cm).
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (2 entries)
- Days to follow up: 320 days; Disease response: With Tumor; Karnofsky performance status: 90.
- Days to follow up: 385 days (1.1 years); Progression or recurrence: Yes; Days to recurrence: 245 days.

Other clinical attributes
- Weight: 102.2 kg; Height: 193 cm; BMI: 27.44.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00674-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
- Sample C3L-00674-71: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 200 mg; Time between excision and freezing: 29 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00674-21: Section location: Frontal Lobe; Percent tumor nuclei: 70; Percent necrosis: 10.
- Sample C3L-00674-72: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 0.3 mg.
